Somatic mutation profile of tumor specimen TCGA-DU-7007-01A (aliquot TCGA-DU-7007-01A-11D-2024-08) from TCGA case TCGA-DU-7007, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 33.5 years (12,245 days).
Specimen TCGA-DU-7007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 167058d7-5f30-440e-93b8-b1e9940ed6d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7007-10A (Blood Derived Normal), aliquot TCGA-DU-7007-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1daacd97-7b64-478c-b526-9120bc19d243

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Nonsense Mutation 2, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.375+1G>C p.X125_splice | Splice Site (SNP) | VAF 56/72 reads (78%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ACER1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs768150338, COSV56835760, COSV56837054; called by muse, mutect2, varscan2
- AMFR | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs147760918; called by muse, mutect2
- APOBEC3H | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1254444554, COSV62378961; called by muse, mutect2, varscan2
- BICD2 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63547854; called by muse, mutect2, varscan2
- BNIP2 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV51109491; called by muse, mutect2
- CCDC33 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV58358411; called by muse, mutect2, varscan2
- CNTN3 | c.701C>G p.P234R | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV55184831; called by muse, mutect2, varscan2
- COL14A1 | c.3256A>T p.K1086* | Nonsense Mutation (SNP) | VAF 56/121 reads (46%) | catalogued as COSV52869308; called by muse, mutect2, varscan2
- CXXC4 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV101182322, COSV67296982; called by muse, mutect2, varscan2
- DLX5 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431242250, COSV56034432; called by muse, mutect2, varscan2
- FGF7 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs753270506, COSV51067637; called by muse, varscan2
- GABRA6 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50894858; called by muse, mutect2, varscan2
- GPR32 | c.36T>A p.S12R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1029805697, COSV54515675; called by muse, mutect2, varscan2
- GPRC5D | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs370153735; called by muse, mutect2, varscan2
- HELZ | c.4268A>G p.Y1423C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV62381083; called by muse, mutect2, varscan2
- KEL | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs754663945, CM165861, COSV100787334, COSV62337997; called by muse, mutect2, varscan2
- M6PR | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 58/495 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50004013; called by muse, mutect2, varscan2
- MUC17 | c.4612C>G p.P1538A | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV60303949; called by muse, mutect2, varscan2
- NPAP1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs200510789, COSV100274923, COSV61511489; called by muse, mutect2, varscan2
- OLFM3 | c.632G>A p.R211H (on ENST00000338858 / NM_001288821.1; = p.R191H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs776719691, COSV58801848, COSV58804479; called by muse, mutect2, varscan2
- PAX4 | c.248C>G p.P83R | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as rs1260268236, COSV58391375; called by muse, mutect2, varscan2
- RPP30 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.12); catalogued as COSV53296046; called by muse, mutect2, varscan2
- SKP2 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56952951; called by muse, mutect2, varscan2
- SPA17 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57033272; called by muse, mutect2, varscan2
- ZNF629 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1316597740, COSV52700735; called by muse, mutect2
- ROS1 | c.46del p.T16Lfs*15 | Frame Shift Del (DEL) | VAF 55/157 reads (35%) | called by mutect2, pindel, varscan2
- ATG2A | c.1821G>T p.L607= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV65968973; called by muse, mutect2
- BSDC1 | c.918C>A p.S306= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV61983519; called by muse, mutect2, varscan2
- COL4A2 | c.3648C>T p.H1216= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs374779953; called by muse, mutect2
- COL4A5 | c.4815A>T p.A1605= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV60372521; called by muse, mutect2, varscan2
- DBH | c.321G>A p.G107= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55042418; called by muse, mutect2, varscan2
- DNAH10 | c.5700C>T p.T1900= (on ENST00000409039; = p.T1839= on NM_207437.3) | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as rs1451742820, COSV69002309; called by muse, mutect2, varscan2
- GPR139 | c.873G>C p.R291= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as COSV100429569, COSV100429864, COSV58505156; called by muse, mutect2, varscan2
- OR2A4 | c.210C>T p.I70= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs773477863, COSV100199594; called by muse, varscan2
- PLCH1 | c.4869C>T p.T1623= (on ENST00000340059 / NM_001130960.2; = p.T1615= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV58210548; called by muse, mutect2, varscan2
- STX19 | c.592T>C p.L198= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV57401933; called by muse, mutect2, varscan2
- TTYH2 | c.1005C>T p.P335= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV53913505; called by muse, mutect2, varscan2
- ZBBX | c.2166C>A p.T722= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV56801971; called by muse, mutect2, varscan2
- TTN | c.10360+4752T>G | Intron (SNP) | VAF 23/139 reads (17%) | catalogued as COSV100589290; called by muse, mutect2, varscan2
